Somatic mutation profile of tumor specimen 0DJO5C from CCDI case PBBMCX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pituitary adenoma, NOS; Tissue or organ of origin: Pituitary gland; Age at diagnosis: 18.1 years (6,621 days).
Specimen 0DJO5C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ae0118e-6b48-4394-83e9-2bba67971424.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c8c2ee7-9c78-45b8-a6ee-f64657f92bae

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRAK3 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 93/988 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs199538395; called by muse, mutect2
